Somatic mutation profile of tumor specimen 0DRE0U from CCDI case PBCGDN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Posterior wall of oropharynx; Age at diagnosis: 18.6 years (6,811 days).
Specimen 0DRE0U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c193177-ff6d-4dd4-9b53-fce2369cd93e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRE0I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31229f76-b1a9-49b3-be36-f2d59693c5b4

The open-access MAF lists 101 somatic variants for this specimen: 63 protein-altering or splice-affecting, 25 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 25, Intron 7, Splice Region 4, Splice Site 3, Nonsense Mutation 3, 3'UTR 2, 5'UTR 2, Frame Shift Del 1, RNA 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375468649; called by muse, mutect2, varscan2
- CACNA1S | c.5380C>T p.R1794* | Nonsense Mutation (SNP) | VAF 88/447 reads (20%) | catalogued as rs775764917; called by muse, mutect2, varscan2
- CDK14 | c.369G>A p.S123= (on ENST00000380050 / NM_001287135.2; = p.S105= on NM_012395.3) | Splice Region (SNP) | VAF 42/963 reads (4%) | catalogued as rs55722725, COSV56028454, COSV56040466; called by muse, mutect2
- CEP78 | c.1190G>A p.R397H (on ENST00000424347 / NM_001349840.2; = p.R398H on NM_032171.3) | Missense Mutation (SNP) | VAF 202/890 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780215853; called by muse, varscan2
- COL18A1 | c.2404G>T p.G802* (on ENST00000359759 / NM_130444.3; = p.G567* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 54/309 reads (17%) | catalogued as COSV62704301; called by muse, mutect2, varscan2
- FHDC1 | c.2974C>A p.L992I | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775695946; called by muse, mutect2, varscan2
- GCLM | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 218/1326 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100934018; called by muse, mutect2, varscan2
- GPR37L1 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.03); catalogued as rs777374958, COSV66162864; called by muse, mutect2, varscan2
- HERC2 | c.8284C>A p.R2762S | Missense Mutation (SNP) | VAF 210/817 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV55321586; called by muse, mutect2, varscan2
- HOXA1 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 121/1147 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs765543665; called by muse, mutect2, varscan2
- IGSF22 | c.2404C>T p.P802S (on ENST00000319338; = p.P903S on NM_173588.4) | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV55010124, COSV55011190; called by muse, mutect2, varscan2
- INTS1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 16/541 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1306198637; called by muse, mutect2
- INTS11 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs577701965; called by muse, mutect2, varscan2
- MAPT | c.1918G>A p.V640M (on ENST00000262410 / NM_001377265.1; = p.V248M on NM_005910.5) | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs369217369; called by muse, mutect2, varscan2
- MYH2 | c.5305G>A p.A1769T | Missense Mutation (SNP) | VAF 117/560 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs550869991, COSV55439897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.17093del p.G5698Efs*14 | Frame Shift Del (DEL) | VAF 112/740 reads (15%) | catalogued as COSV50811494; called by mutect2, pindel, varscan2
- PDCD7 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 157/628 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768472715, COSV52600290; called by muse, mutect2, varscan2
- PGAM4 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 28/658 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs782286209, COSV58443759; called by muse, mutect2
- PUS7 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 137/882 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1262465169; called by muse, mutect2, varscan2
- RP1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 61/538 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV55119207; called by muse, mutect2, varscan2
- RTN3 | c.985G>T p.V329L (on ENST00000377819 / NM_001265589.2; = p.V310L on NM_201428.3) | Missense Mutation (SNP) | VAF 146/829 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs924037416; called by muse, mutect2, varscan2
- SDK1 | c.6637G>A p.V2213M | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs981320763, COSV101270051; called by muse, mutect2, varscan2
- SEPTIN1 | c.699+5G>A | Splice Region (SNP) | VAF 95/369 reads (26%) | catalogued as rs1185331948; called by muse, mutect2, varscan2
- SGCZ | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 49/1795 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV66047108; called by muse, mutect2
- SLX4 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 60/363 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as rs763869769; called by muse, mutect2, varscan2
- SP4 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 126/894 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.108); catalogued as rs1451040159, COSV99755102; called by muse, mutect2, varscan2
- TBX5 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 127/689 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs1207284425, COSV100090367, COSV59863219; called by muse, mutect2, varscan2
- TG | c.3023G>A p.R1008H | Missense Mutation (SNP) | VAF 117/1032 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.594); catalogued as rs758531254, COSV99604168; called by muse, mutect2, varscan2
- ZNFX1 | c.4879C>T p.R1627C | Missense Mutation (SNP) | VAF 103/460 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs959408032; called by muse, mutect2, varscan2
- ABCA13 | c.898-1G>T p.X300_splice | Splice Site (SNP) | VAF 70/507 reads (14%) | called by muse, mutect2, varscan2
- CCDC39 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 246/1074 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by mutect2, varscan2
- CCT5 | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 221/1281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFTR | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 147/1196 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CMYA5 | c.2162T>C p.L721S | Missense Mutation (SNP) | VAF 108/715 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CNOT4 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 678/1996 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- DOCK1 | c.4516A>G p.S1506G | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPBP1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 94/601 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GSTA1 | c.414+1G>T p.X138_splice | Splice Site (SNP) | VAF 106/574 reads (18%) | called by mutect2, varscan2
- GZF1 | c.919_920insT p.D307Vfs*12 | Frame Shift Ins (INS) | VAF 53/399 reads (13%) | called by mutect2, pindel, varscan2
- IFNA16 | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 136/637 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGI3 | c.3516C>A p.S1172R | Missense Mutation (SNP) | VAF 417/1171 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC16 | c.24580G>T p.E8194* | Nonsense Mutation (SNP) | VAF 123/471 reads (26%) | called by muse, mutect2, varscan2
- MYLK2 | c.1408G>T p.V470L | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- MYO18A | c.3785A>T p.E1262V | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR0B1 | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRF1 | c.468G>T p.V156= | Splice Region (SNP) | VAF 74/656 reads (11%) | called by muse, mutect2, varscan2
- OR2J1 | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 25/823 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6B1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 133/804 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PAPPA2 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 149/923 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POFUT2 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 261/647 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTGFRN | c.1630_1639+26delinsCATTAGAAGGTAGGAACTTTTTTCTTGTTATTCA p.X544_splice | Splice Site (DEL) | VAF 83/940 reads (9%) | called by pindel, varscan2*
- SAC3D1 | c.993C>A p.S331R | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- SERPINA4 | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 113/462 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SNX24 | c.63G>T p.V21= | Splice Region (SNP) | VAF 119/793 reads (15%) | called by muse, mutect2, varscan2
- SOX13 | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 104/233 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTLC3 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STXBP5 | c.3364A>T p.T1122S (on ENST00000321680 / NM_001127715.2; = p.T1086S on NM_139244.4) | Missense Mutation (SNP) | VAF 193/878 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TDRD9 | c.1928A>G p.H643R | Missense Mutation (SNP) | VAF 188/828 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TMEM182 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 193/1072 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TRAF3IP1 | c.1686G>T p.E562D | Missense Mutation (SNP) | VAF 155/691 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- VWA8 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ZFYVE1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 100/491 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ZNF479 | c.492A>T p.K164N | Missense Mutation (SNP) | VAF 139/1113 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); called by mutect2, varscan2
- B4GALNT4 | c.63G>A p.L21= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as rs1450405222; called by muse, mutect2, varscan2
- CASZ1 | c.1206C>T p.S402= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs370703881; called by muse, mutect2, varscan2
- CEP97 | c.408A>T p.I136= | Silent (SNP) | VAF 262/1167 reads (22%) | called by muse, mutect2, varscan2
- DGKI | c.972C>A p.I324= | Silent (SNP) | VAF 111/943 reads (12%) | catalogued as COSV55937541; called by muse, mutect2, varscan2
- DICER1 | c.2316G>T p.V772= | Silent (SNP) | VAF 184/752 reads (24%) | catalogued as COSV58629358; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1626T>C p.N542= | Silent (SNP) | VAF 30/682 reads (4%) | called by muse, mutect2
- FAM170B | c.135G>C p.S45= | Silent (SNP) | VAF 48/430 reads (11%) | called by muse, mutect2, varscan2
- FBN3 | c.4590C>T p.P1530= | Silent (SNP) | VAF 90/282 reads (32%) | called by muse, mutect2, varscan2
- FCGRT | c.465C>T p.P155= | Silent (SNP) | VAF 157/450 reads (35%) | catalogued as rs1285480672; called by muse, mutect2, varscan2
- KIAA1958 | c.1296T>A p.R432= | Silent (SNP) | VAF 175/793 reads (22%) | called by muse, mutect2, varscan2
- LPA | c.5658T>C p.S1886= | Silent (SNP) | VAF 140/753 reads (19%) | called by muse, mutect2, varscan2
- NANOGNB | c.324A>G p.L108= | Silent (SNP) | VAF 94/565 reads (17%) | called by muse, mutect2, varscan2
- NGFR | c.432C>T p.T144= | Silent (SNP) | VAF 65/227 reads (29%) | catalogued as rs915930410; called by muse, mutect2, varscan2
- OR14J1 | c.261C>T p.N87= | Silent (SNP) | VAF 146/826 reads (18%) | catalogued as rs755742835, COSV65845642; called by muse, mutect2, varscan2
- PRDM1 | c.1611G>A p.A537= | Silent (SNP) | VAF 36/630 reads (6%) | catalogued as rs760254920; called by muse, mutect2
- SEMA6A | c.117G>A p.P39= | Silent (SNP) | VAF 120/1044 reads (11%) | catalogued as rs374336600; called by muse, mutect2, varscan2
- SEMA6B | c.1264C>T p.L422= | Silent (SNP) | VAF 71/404 reads (18%) | catalogued as rs763015109; called by muse, mutect2, varscan2
- SORCS3 | c.2658G>C p.A886= | Silent (SNP) | VAF 123/488 reads (25%) | catalogued as COSV100863832, COSV63793931, COSV63794340; called by muse, mutect2, varscan2
- SOWAHA | c.135C>G p.A45= | Silent (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2, varscan2
- TLR4 | c.141A>G p.K47= (on ENST00000355622 / NM_138554.5; = p.K7= on NM_003266.4) | Silent (SNP) | VAF 119/717 reads (17%) | catalogued as rs1410888763; called by muse, mutect2, varscan2
- TNNI3K | c.2109C>T p.N703= | Silent (SNP) | VAF 51/805 reads (6%) | catalogued as rs573557170, COSV58560907; called by muse, mutect2
- TOP2B | c.1449A>G p.G483= (on ENST00000264331 / NM_001330700.2; = p.G478= on NM_001068.3) | Silent (SNP) | VAF 237/981 reads (24%) | called by muse, mutect2, varscan2
- TPH2 | c.177C>G p.T59= | Silent (SNP) | VAF 115/1542 reads (7%) | catalogued as rs201100007; called by muse, mutect2
- TTC9C | c.471C>T p.S157= | Silent (SNP) | VAF 225/1283 reads (18%) | called by muse, mutect2, varscan2
- WDFY1 | c.537C>A p.I179= | Silent (SNP) | VAF 155/975 reads (16%) | called by muse, mutect2, varscan2
- AKAP8 | chr19:15379831 del C | 5'Flank (DEL) | VAF 73/197 reads (37%) | called by mutect2, pindel, varscan2
- ALDH7A1 | c.1489+29A>G | Intron (SNP) | VAF 105/429 reads (24%) | called by muse, mutect2, varscan2
- ANP32E | c.*7C>T | 3'UTR (SNP) | VAF 137/882 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.*3526G>A | 3'UTR (SNP) | VAF 79/548 reads (14%) | catalogued as rs375608903, COSV100082406; called by muse, mutect2, varscan2
- B4GALNT1 | c.-1-94G>A | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as rs780048927; called by muse, mutect2, varscan2
- ECE2 | c.2259+82C>T | Intron (SNP) | VAF 10/50 reads (20%) | catalogued as rs776314341, COSV62570931; called by muse, mutect2, varscan2
- ENPP7P2 | n.76A>G | RNA (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- FADS6 | c.412-9C>A | Intron (SNP) | VAF 43/205 reads (21%) | called by muse, mutect2, varscan2
- OAZ2 | c.353+41C>T | Intron (SNP) | VAF 52/186 reads (28%) | called by muse, mutect2, varscan2
- RNFT1 | c.-69C>T | 5'UTR (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- SNED1 | c.3817+88G>T | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- STX18 | c.912+36C>T | Intron (SNP) | VAF 32/159 reads (20%) | catalogued as rs761091540; called by muse, mutect2, varscan2
- ZNF853 | c.-15G>T | 5'UTR (SNP) | VAF 71/408 reads (17%) | called by muse, mutect2, varscan2
